CCDI case PBCLUV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/4bd21db6-4532-494e-9975-e7b11b71d4c6

Demographics
Sex at birth: male; Race: white.

Biospecimens (3 samples)
- Sample 0DUVT6: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DUVTF: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DUVTS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
